Somatic mutation profile of tumor specimen TARGET-10-PARDLZ-09A (aliquot TARGET-10-PARDLZ-09A-01D) from TARGET case TARGET-10-PARDLZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.5 years (4,199 days).
Specimen TARGET-10-PARDLZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6a0f156-0980-42b4-87f5-3cf4956e92c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDLZ-10A (Blood Derived Normal), aliquot TARGET-10-PARDLZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9366bb8-e959-49e3-8b2c-5b3285b6b446

The open-access MAF lists 40 somatic variants for this specimen: 20 protein-altering or splice-affecting, 9 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Intron 5, 5'UTR 3, RNA 2, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNASE2B | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs146223730; called by muse, mutect2, varscan2
- HNF4G | c.112C>T p.R38C (on ENST00000354370 / NM_001330561.2; = p.R85C on NM_004133.5) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772036366, COSV62965321; called by muse, mutect2, varscan2
- IGFBP3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV51872225; called by muse, mutect2
- MGAM2 | c.5356C>A p.Q1786K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as rs1393809136; called by muse, mutect2, varscan2
- NELL2 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV61576217; called by muse, mutect2, varscan2
- PTPRN | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.294); catalogued as rs1399419251, COSV99833986; called by mutect2, varscan2
- SUN2 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 8/83 reads (10%) | catalogued as COSV53308030; called by muse, mutect2, varscan2
- SYDE2 | c.3488G>A p.R1163Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs775631372, COSV58323150; called by muse, mutect2, varscan2
- TAT | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs762641460; called by muse, mutect2, varscan2
- TCEAL4 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 70/71 reads (99%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs185783033, COSV65463539; called by muse, mutect2, varscan2
- THEGL | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs764561221; called by muse, mutect2, varscan2
- ZNF462 | c.6518C>T p.P2173L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752141501; called by muse, mutect2, varscan2
- ALPK1 | c.437A>T p.Q146L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BLOC1S5 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BTAF1 | c.1413C>A p.F471L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.04); called by muse, mutect2
- CENPK | c.31A>G p.T11A | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- RADX | c.2033A>G p.D678G | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2
- SEC23A | c.914A>G p.E305G | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TSPYL1 | c.161C>A p.S54* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- TSPYL5 | c.695A>T p.Q232L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ACTL9 | c.600C>T p.H200= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV61004826; called by muse, mutect2, varscan2
- ATP5F1B | c.453T>C p.P151= | Silent (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- ATR | c.4881G>A p.Q1627= | Silent (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- CCKBR | c.117C>T p.C39= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs769224527, COSV58101056; called by muse, mutect2, varscan2
- ITGA2B | c.1335C>A p.G445= | Silent (SNP) | VAF 7/173 reads (4%) | called by muse, mutect2
- KLHL4 | c.1440C>T p.V480= | Silent (SNP) | VAF 55/58 reads (95%) | catalogued as rs757049284, COSV64143472; called by muse, mutect2, varscan2
- LCT | c.5382G>A p.A1794= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs1443619474, COSV51545337; called by muse, mutect2, varscan2
- PSKH1 | c.1059G>A p.P353= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs776470919; called by muse, mutect2, varscan2
- TNNI1 | c.264C>T p.L88= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as rs1266990868; called by muse, mutect2
- ADRA2C | c.*144C>T | 3'UTR (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- GRIA4 | c.2544+72A>T | Intron (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.576T>C | RNA (SNP) | VAF 6/96 reads (6%) | catalogued as rs879149315; called by muse, mutect2
- LMO3 | c.-142G>A | 5'UTR (SNP) | VAF 15/30 reads (50%) | catalogued as COSV53785550; called by muse, mutect2, varscan2
- LRP4 | c.2093-29G>T | Intron (SNP) | VAF 43/82 reads (52%) | called by muse, mutect2, varscan2
- NECTIN1 | c.79+14705del | Intron (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- OR2AJ1 | c.-14A>G | 5'UTR (SNP) | VAF 12/29 reads (41%) | catalogued as COSV59089408; called by muse, mutect2, varscan2
- PCDHGA7 | c.-86C>A | 5'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- RPL14P1 | n.353C>T | RNA (SNP) | VAF 10/56 reads (18%) | catalogued as rs756988602; called by mutect2, varscan2
- SLC19A2 | c.1223+33A>G | Intron (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- SMARCB1 | c.363-2237C>G | Intron (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2, varscan2
